Surgical pathology report (de-identified scan), TCGA case TCGA-CM-5862, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-5862-01A (Primary Tumor).

[page 1 of 6]
....

Clinical Diagnosis & History:

[REDACTED] with right colon mass and [REDACTED]

Specimens Submitted:

1: SP: Colon, right; hemicolectomy

DIAGNOSIS:

1. SP: Colon, right; hemicolectomy:

Tumor Type:

Adenocarcinoma

Histologic Grade:

Moderately differentiated

Tumor Location:

Ascending colon

Tumor Size:

Length is 5.5 cm

Width is 6.5 cm

Tumor Budding:

Absent

Increased Tumor Infiltrating Lymphocytes:

Absent

Precursor Lesions:

Not identified

Deepest Tumor Invasion:

Subserosal adipose tissue and/or mesenteric fat

Gross Tumor Perforation:

Not identified

Lymphovascular Invasion:

Identified

Large Venous Invasion:

Not Identified

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

Polyyps/Mucosa Dysplasia (away from the carcinoma):

Tubular adenoma; number: 2

Hyperplastic polyp; number: 1

Non-Neoplastic Bowel:

Unremarkable

** Continued on next page **

[page 2 of 6]
Appendix:

Fibrous obliteration of the lumen

Lymph Nodes:

Number with metastasis: 1

Total number examined: 24

Tumor deposits in pericorectal soft tissue:

Identified

Tumor Staging (AJCC 7th Edition):

pT3 (Tumor invades through the muscularis propria into pericorectal tissues)

Lymph Node Stage (AJCC 7th Edition):

N1 (Metastasis in 1-3 regional lymph nodes)

PENDING K-RAS.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result

Special Stain
KRAS

Comment

Gross Description:

1).The specimen is received fresh, labeled "Right hemicolectomy colon" and consists of a segment of terminal ileum, cecum with attached appendix and ascending colon. The terminal ileum measures 7.5 cm in length and 3.5 cm in circumference at the proximal resected margin. The remaining colon measures 19 in length with a circumference of 8 cm at the distal resected margin. The attached appendix measures 6.5 cm in length and averages 0.7 cm in diameter. The appendiceal and intestinal serosa is pink tan and smooth. Focally hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to 5 cm in thickness. The specimen is opened to reveal a circumferential, centrally ulcerative, fungating, brown tan tumor measuring 5.5 cm in length, 6.5 cm in width, and 2.0 cm in height. On cut section of the tumor, it measures 2.5 cm in maximum depth and abuts the black inked radial margin. The tumor is located 6.3 cm from the ileocecal valve and 6 cm from the distal resected margin. Also identified, 4.0 cm from the ileocecal valve and 4.2 cm from the main tumor mass, there is a brown-tan polypoid structure measuring 1.8 x 0.8 x 0.7 cm. The remaining mucosa shows brown-tan folded appearance and several polypoid areas measuring up to 0.4 x 0.3 cm in greatest dimensions, which are entirely submitted. The specimen is submitted for lymph node dissection. The attached adipose tissue is thoroughly examined and all identified lymph nodes are submitted. Representative sections of the specimen are submitted

** Continued on next page **

[page 3 of 6]
----- Page 3 of 3
for permanent sections and for TPS.

Summary of sections:

PM - proximal margin shave

DM - distal margin shave

T - tumor (box 11 and 12, 13 and 14 are full-thickness section of tumor with underlying cause of lymph node, bisected)

APP - appendix representative sections

RS -representative sections

LN - lymph nodes

LPOL-largest polypoid area

POL-polypoid areas

Summary of Sections:

Part 1: SP: Colon, right; hemicolectomy

Block	Sect.	Site	PCs
2		app	2
1		dm	1
7		LN	18
2		lpol	2
1		pm	1
1		pol	1
1		rs	1
6		T	6

** End of Report **

[page 4 of 6]
.....

Specimens Submitted:

1: DM SUBMITTED 10 UNSTAINED SLIDES AND 1 H&E, RIGHT COLON

Test Performed:

KRAS Gene Exon 2 mutation analysis (codons 12 and 13)

DNA quality: good.

Methodology:

PCR was performed to amplify exon 2 of the KRAS gene from genomic DNA prepared from the submitted tissue. The PCR product was analyzed on an ABI 3730 DNA sequencer and the sequences were compared to control sequences.

DIAGNOSTIC INTERPRETATION:

Negative for KRAS exon 2 mutation.

Technical sensitivity: This assay cannot detect a KRAS exon 2 mutation if the proportion of tumor cells in the sample studied is less than 25%.

1. This result cannot be used as sole evidence for or against cancer and has to be interpreted in the context of all available clinical and pathological information.

2. This test was developed and its performance characteristics determined by the Laboratory of Diagnostic Molecular Pathology. It has not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance is not necessary. This test is used for clinical purposes. Pursuant to the requirements of CLIA '88, our laboratory has established the accuracy and precision of this test. This test has been approved by [REDACTED] as a laboratory specific assay.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF

** Continued on next page **

[page 5 of 6]
----- Page 2 of 3
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

Procedures/Addenda

Addendum

Date Ordered:

Date Complete:

Date Reported:

Addendum Diagnosis

NONE OF THESE MUTATIONS WERE DETECTED IN THE TUMOR.

CLINICAL PANEL

Gene Codon

BRAF V600

EGFR L858

INVESTIGATIONAL PANEL

Gene Codon	Gene Codon	Gene Codon
AKT1 E17	EGFR L861	NRAS G12
BRAF G469	ERBB2 L755	NRAS G13
BRAF D594	ERBB2 D769	NRAS Q61
EGFR E709	ERBB2 V777	PIK3CA R88
EGFR G719	KRAS Q61	PIK3CA N345
EGFR D761	KRAS K117	PIK3CA C420
EGFR S768	KRAS A146	PIK3CA E542
EGFR R776	MEK1 Q56	PIK3CA E545
EGFR T790	MEK1 K57	PIK3CA M1043
EGFR T854	MEK1 D67	PIK3CA H1047

Diagnostic sensitivity: This finding does not exclude the possibility of other mutations.

Technical sensitivity: This test may not detect certain mutations if the proportion of tumor cells in the sample studied is less than 10%.

Test Performed:

Sequenom mass-spectrometry genotyping for specific mutations in 8 genes: AKT1, BRAF, EGFR, ERBB2, KRAS, MEK1 (MAP2K1), NRAS, and PIK3CA

Methodology:

The specific mutations are detected by amplification of the corresponding exons by polymerase chain reaction (PCR), followed by a single base extension at the site of the point mutation. The single base extension product is detected by tandem mass-spectrometry on a Sequenom MassArray Spectrometer.

Addendum Comment

PLATE# P10-42

** Continued on next page **

[page 6 of 6]
This result cannot be used as sole evidence for or against cancer and has to be interpreted in the context of all available clinical and pathological information.

This test was developed, and its performance characteristics determined, by the [REDACTED] It has not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance is not necessary. This test is used for clinical purposes. Pursuant to the requirements of CLIA ' [REDACTED] our laboratory has established the accuracy and precision of this test.

The results of the investigational panel are for investigational use only.

[REDACTED]

** End of Report **

Source: NCI Genomic Data Commons file 00c0279c-c926-4899-909f-b1c77798e3fa (TCGA-CM-5862.5679DF5F-FC93-45C4-84EE-B4B4350B6B51.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).